Somatic mutation profile of tumor specimen TCGA-L5-A4OU-01A (aliquot TCGA-L5-A4OU-01A-11D-A28B-09) from TCGA case TCGA-L5-A4OU, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: GX; Age at diagnosis: 81.2 years (29,674 days).
Specimen TCGA-L5-A4OU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbdbfdf8-0ebe-49ec-b745-33e46f2a7288.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OU-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OU-11A-11D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a56704f7-ad7b-4769-8359-150e7251fd36

The open-access MAF lists 191 somatic variants for this specimen: 129 protein-altering or splice-affecting, 59 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 117, Silent 59, Nonsense Mutation 5, Splice Site 2, Frame Shift Del 2, Intron 1, Frame Shift Ins 1, RNA 1, 3'UTR 1, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2320_2322dup p.M774dup | In Frame Ins (INS) | VAF 210/274 reads (77%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- MYH7 | c.2155C>T p.R719W | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs121913637, CM941086, COSV62523084; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.821T>G p.V274G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520006, COSV52662012, COSV52709979, COSV52761348, COSV53124293; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.3805C>T p.R1269* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as rs989536317, COSV100253329; called by muse, mutect2, varscan2
- ACTN3 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1369024192, COSV59748051; called by muse, mutect2, varscan2
- ARHGAP31 | c.2777C>T p.A926V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771980065, COSV51791002; ClinVar: uncertain significance; called by mutect2, varscan2
- ATP1A2 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1282248061, CM105895, COSV63405089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFAP77 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.229); catalogued as COSV58018026; called by muse, mutect2, varscan2
- CHL1 | c.1406G>A p.R469K (on ENST00000397491 / NM_001253387.1; = p.R485K on NM_006614.4) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.122); catalogued as COSV99852370; called by muse, mutect2, varscan2
- DOCK2 | c.5402A>G p.K1801R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.054); catalogued as rs143896166; called by muse, mutect2, varscan2
- ENPP6 | c.850T>C p.S284P | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.262); catalogued as rs1459184050; called by muse, mutect2, varscan2
- EPHA2 | c.1552G>A p.G518S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs767658655, COSV64453749; called by muse, mutect2, varscan2
- ERG | c.1070G>A p.R357H (on ENST00000398919 / NM_001243428.1; = p.R333H on NM_004449.4) | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55736705; called by muse, mutect2
- ESR1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV52802515; called by muse, mutect2, varscan2
- FLT1 | c.2878G>A p.V960I | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs554058758, COSV56725597; called by muse, mutect2, varscan2
- FMNL3 | c.2855A>T p.K952M | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV53301880; called by muse, mutect2, varscan2
- GPN1 | c.575A>C p.D192A | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1396337706; called by muse, mutect2
- GRIN2C | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs768559389, COSV53117949; called by muse, mutect2, varscan2
- H2AC15 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.627); catalogued as rs144042626; called by muse, mutect2, varscan2
- INSC | c.605A>G p.Q202R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.114); catalogued as COSV65412329; called by muse, mutect2, varscan2
- LRP2 | c.7621T>G p.F2541V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV55571157; called by muse, mutect2, varscan2
- MATN4 | c.1303C>A p.R435S (on ENST00000372754; = p.R394S on NM_003833.4) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | PolyPhen probably damaging (1); catalogued as COSV61352739; called by muse, mutect2, varscan2
- MDGA1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs866272284, COSV51792201; called by muse, mutect2, varscan2
- MED12L | c.5473T>G p.F1825V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs750224787; called by mutect2, varscan2
- MED25 | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as rs1344347388; called by muse, mutect2, varscan2
- NLRP11 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs945392173, COSV64085396, COSV64088549; called by muse, mutect2, varscan2
- OR4D9 | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs758876713; called by muse, mutect2, varscan2
- PARM1 | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764261196; called by muse, mutect2, varscan2
- PCLO | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs370346756, COSV61623402; called by muse, mutect2, varscan2
- PLEC | c.13090C>T p.L4364F (on ENST00000322810 / NM_201380.4; = p.L4254F on NM_000445.5) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs782010335; called by muse, mutect2, varscan2
- PSAT1 | c.655T>C p.F219L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as rs200130440; called by muse, mutect2, varscan2
- RANBP17 | c.1886T>C p.L629P | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866990902; called by muse, mutect2, varscan2
- RASA1 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1305400293, COSV57198473; called by muse, mutect2, varscan2
- RFXANK | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs559367724, COSV50763390; called by muse, mutect2, varscan2
- RHBDF1 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs754018001, COSV51956637; called by muse, mutect2, varscan2
- SCO2 | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376904278; called by muse, mutect2
- SELENOV | c.1004T>G p.I335S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59064499; called by muse, mutect2, varscan2
- SSBP2 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs1314141774; called by muse, mutect2, varscan2
- THEMIS | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as rs199738235; called by muse, mutect2, varscan2
- TLE1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as rs374215758; called by muse, mutect2, varscan2
- USP21 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.769); catalogued as rs1297104547, COSV99237313; called by muse, mutect2, varscan2
- ZKSCAN7 | c.2143G>A p.G715R | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs774897399; called by muse, mutect2
- ZNF254 | c.1159T>G p.F387V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61643202; called by muse, mutect2
- ZNF676 | c.146A>G p.K49R (on ENST00000650058; = p.K17R on NM_001001411.3) | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV68092014; called by muse, mutect2, varscan2
- ZNF677 | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs764255088; called by muse, mutect2, varscan2
- ZNF677 | c.45A>G p.I15M | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1216631273; called by muse, mutect2, varscan2
- ABCA13 | c.11711A>G p.K3904R | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.959); called by muse, mutect2
- ABHD6 | c.734A>C p.K245T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ADAM18 | c.884A>T p.K295I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- C16orf89 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); called by muse, mutect2
- CCDC191 | c.1295A>C p.K432T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CHD1 | c.2737G>A p.V913I | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CHD3 | c.1319A>G p.E440G | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- CHTF8 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CNTNAP3 | c.1582T>G p.L528V | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- COL11A1 | c.924A>C p.E308D | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCLRE1A | c.1717A>G p.K573E | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- DLG4 | c.1265C>T p.S422F (on ENST00000399506 / NM_001321075.3; = p.S465F on NM_001365.4) | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- EGF | c.3338C>T p.P1113L | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF5A2 | c.321A>C p.E107D | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ELK4 | c.236A>C p.K79T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ERLEC1 | c.1408T>G p.L470V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EYA3 | c.1445C>G p.T482S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FCRL6 | c.894A>T p.Q298H | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- FOCAD | c.890T>G p.V297G | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- FOXRED2 | c.2022del p.Q675Sfs*104 | Frame Shift Del (DEL) | VAF 24/123 reads (20%) | called by mutect2, pindel, varscan2
- GTSE1 | c.1090T>C p.S364P | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- H3C12 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- HDAC4 | c.2996C>A p.P999H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HSPA1B | c.1694C>G p.A565G | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HYDIN | c.12959T>C p.F4320S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IKZF2 | c.1134C>A p.N378K | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IMPG2 | c.947A>G p.E316G | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- INPP5F | c.1598A>C p.K533T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- JAKMIP2 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KIF7 | c.2411A>C p.K804T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); called by muse, mutect2
- LAMA1 | c.337T>G p.L113V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LASP1 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- MARCHF4 | c.116A>C p.K39T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MCFD2 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP2 | c.1035A>T p.E345D | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2
- NGFR | c.311A>T p.D104V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NKPD1 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLGN4X | c.890C>T p.T297I | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NOTCH1 | c.1306T>C p.F436L | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NPIPB15 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NUP210 | c.680A>G p.Y227C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR1K1 | c.55A>C p.T19P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- OR5H15 | c.219del p.S74Hfs*4 | Frame Shift Del (DEL) | VAF 14/129 reads (11%) | called by mutect2, varscan2
- PATZ1 | c.1810_1812del p.K604del | In Frame Del (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2
- PCDHB6 | c.246T>G p.D82E | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.557); called by muse, mutect2
- PCSK2 | c.565T>G p.F189V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.83); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PDGFRB | c.2653G>A p.D885N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PGM2L1 | c.1168T>C p.S390P | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PHACTR2 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2
- PHYH | c.177A>C p.K59N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- PRUNE2 | c.7815A>C p.E2605D | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- RIMS2 | c.3633A>C p.Q1211H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.965); called by muse, mutect2
- RIPOR2 | c.1787G>T p.C596F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RNF41 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS6KL1 | c.998C>A p.A333D | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SAE1 | c.287T>A p.L96* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- SCG2 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEC16A | c.6545A>G p.Y2182C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- SHB | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIGLEC6 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC12A2 | c.2259dup p.P754Tfs*35 | Frame Shift Ins (INS) | VAF 14/82 reads (17%) | called by mutect2, pindel, varscan2
- SLC25A38 | c.103T>A p.S35T | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLIT1 | c.881A>G p.D294G | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX5 | c.2056A>T p.M686L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.029); called by mutect2, varscan2
- ST8SIA2 | c.653T>C p.V218A | Missense Mutation (SNP) | VAF 22/89 reads (25%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TGFBR3 | c.25A>T p.I9F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMC1 | c.1757T>C p.M586T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- TRDV2 | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSHB | c.163-2A>C p.X55_splice | Splice Site (SNP) | VAF 40/117 reads (34%) | called by muse, mutect2, varscan2
- TUBE1 | c.686A>C p.K229T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2
- UBR4 | c.9039A>C p.E3013D | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- USP24 | c.4622A>C p.E1541A | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VAPB | c.281T>G p.F94C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- WASHC2C | c.3277G>A p.E1093K (on ENST00000336378; = p.E1072K on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- WDR75 | c.2430A>C p.K810N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF285 | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- ZNF521 | c.926A>C p.K309T | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); called by muse, mutect2
- ZNF534 | c.634T>C p.S212P (on ENST00000332323 / NM_001143939.3; = p.S199P on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- ZNF616 | c.616A>T p.I206L | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ZNF707 | c.781T>C p.S261P | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF713 | c.1150C>T p.P384S (on ENST00000633730 / NM_001366796.2; = p.P397S on NM_182633.3) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF84 | c.143-2A>G p.X48_splice | Splice Site (SNP) | VAF 26/176 reads (15%) | called by muse, mutect2, varscan2
- ZNF84 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- A2ML1 | c.3366G>C p.R1122= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV55285118; called by muse, mutect2, varscan2
- ADAM2 | c.675G>A p.L225= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs760595106, COSV55861563; called by muse, mutect2, varscan2
- AHNAK | c.2295G>A p.E765= | Silent (SNP) | VAF 48/177 reads (27%) | called by muse, mutect2, varscan2
- ANKS3 | c.1050C>T p.S350= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- ARSK | c.642T>G p.S214= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- ATR | c.2469T>G p.A823= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- CIB2 | c.312A>G p.R104= | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as rs1567049965; called by muse, mutect2, varscan2
- COL5A1 | c.3765C>A p.G1255= | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- CRMP1 | c.976T>C p.L326= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs1242934346, COSV61482110; called by muse, mutect2, varscan2
- CRTC3 | c.1149T>C p.S383= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- DYNC1H1 | c.12717G>A p.P4239= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs753722628; called by muse, mutect2, varscan2
- ERICH6 | c.1395T>G p.G465= | Silent (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- FAT2 | c.9762C>T p.R3254= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV55812868; called by muse, mutect2, varscan2
- FOXR1 | c.462C>A p.P154= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- GNAS | c.957C>T p.D319= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2
- GRM1 | c.588T>G p.T196= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV51117494, COSV51140435; called by muse, mutect2, varscan2
- GRN | c.525C>T p.H175= | Silent (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- HDAC5 | c.1060C>T p.L354= | Silent (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- HEG1 | c.1158A>G p.R386= | Silent (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- IGDCC3 | c.1188C>T p.A396= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV60076704; called by muse, mutect2, varscan2
- IGSF10 | c.3282T>C p.I1094= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- KCNA3 | c.1338T>A p.G446= | Silent (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- KIF2B | c.661C>A p.R221= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV52126920, COSV52127326; called by muse, mutect2, varscan2
- KIR2DL4 | c.414T>G p.G138= (on ENST00000396284; = p.G99= on NM_001080770.2) | Silent (SNP) | VAF 37/120 reads (31%) | called by muse, mutect2, varscan2
- LYST | c.11244C>T p.P3748= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs1029431150; called by muse, mutect2, varscan2
- MUC21 | c.1374T>G p.T458= | Silent (SNP) | VAF 9/129 reads (7%) | catalogued as COSV66220083; called by muse, mutect2
- NALCN | c.1152C>T p.S384= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1283550500; called by muse, mutect2, varscan2
- NAV2 | c.2631A>G p.E877= (on ENST00000396087 / NM_001244963.2; = p.E854= on NM_145117.5) | Silent (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- NDC80 | c.555A>G p.L185= | Silent (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- NFKB1 | c.1185G>A p.G395= (on ENST00000394820 / NM_001382627.1; = p.G396= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- NPTX2 | c.711C>T p.Y237= | Silent (SNP) | VAF 23/205 reads (11%) | catalogued as rs573416055, COSV55717304, COSV55717885; called by muse, mutect2, varscan2
- OR5B12 | c.150C>T p.D50= | Silent (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- PCDHA10 | c.1122T>C p.S374= | Silent (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2
- PCDHB12 | c.750G>A p.K250= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- PCLO | c.13422T>C p.S4474= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- PCLO | c.3480A>G p.Q1160= | Silent (SNP) | VAF 11/128 reads (9%) | called by muse, mutect2
- PLCL1 | c.2829C>T p.V943= | Silent (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.2277C>T p.A759= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs760590066; called by muse, mutect2, varscan2
- PLOD2 | c.1722A>G p.K574= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs758719698; called by muse, mutect2, varscan2
- PTPN4 | c.2562T>A p.A854= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- R3HDM1 | c.1356T>C p.S452= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- RAG1 | c.2673G>A p.K891= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- RAP2C | c.324A>G p.K108= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- RBFOX1 | c.954C>T p.Y318= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs182244522, COSV100299252, COSV60962133; called by muse, mutect2
- RNF213 | c.12570C>T p.S4190= | Silent (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- RNF43 | c.615G>T p.V205= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, varscan2
- SCAF1 | c.57C>T p.G19= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs200923973; called by muse, mutect2, varscan2
- SCN8A | c.3135C>T p.I1045= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs550579591, COSV61992776; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- SIX5 | c.1836C>T p.H612= | Silent (SNP) | VAF 45/133 reads (34%) | catalogued as rs746328708; called by muse, mutect2, varscan2
- SLC9A5 | c.2553T>C p.S851= | Silent (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- SYCP2L | c.2052G>A p.L684= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs538404243; called by muse, mutect2, varscan2
- TCERG1 | c.882G>A p.Q294= | Silent (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- TECRL | c.684T>C p.T228= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- TRIM56 | c.402G>A p.G134= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs1428026781; called by muse, mutect2
- TRIM58 | c.1243T>C p.L415= | Silent (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- TSHZ2 | c.1029T>G p.S343= | Silent (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- XDH | c.3382T>C p.L1128= | Silent (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- ZNF263 | c.12C>T p.G4= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs765567853; called by muse, mutect2, varscan2
- ZNF408 | c.615G>A p.V205= | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2
- FAM86C1P | n.77C>T | RNA (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- RAB34 | c.*68T>G | 3'UTR (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1802T>G | Intron (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
